Somatic mutation profile of tumor specimen MMRF_1327_1_BM_CD138pos (aliquot MMRF_1327_1_BM_CD138pos_T2_TSE61_L00078) from MMRF case MMRF_1327, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.5 years (26,113 days).
Specimen MMRF_1327_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3856cdb9-e527-4779-910c-16f1de168d99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1327_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1327_1_PB_Whole_C1_TSE61_L00079; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c52c4995-b18d-4855-9953-0083d8b73a0a

The open-access MAF lists 130 somatic variants for this specimen: 71 protein-altering or splice-affecting, 12 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, 3'UTR 34, Silent 12, 5'UTR 6, Frame Shift Del 4, 3'Flank 3, Intron 3, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.825+4_825+7del p.X275_splice | Splice Site (DEL) | VAF 6/58 reads (10%) | catalogued as rs770305133; called by pindel, varscan2
- B3GLCT | c.584C>A p.P195Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100587023, COSV58456339; called by muse, mutect2, varscan2
- CFTR | c.597T>A p.H199Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as CM920147; called by muse, mutect2, varscan2
- CHD5 | c.4648C>T p.P1550S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs199810631; called by muse, mutect2, varscan2
- CSMD1 | c.9738A>T p.K3246N (on ENST00000520002; = p.K3245N on NM_033225.6) | Missense Mutation (SNP) | VAF 71/111 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59357554; called by muse, mutect2, varscan2
- DNAH9 | c.6464C>A p.T2155N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs780337866; called by muse, mutect2, varscan2
- EHD1 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57734907; called by muse, mutect2, varscan2
- FIGNL1 | c.1421G>A p.W474* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as rs746530770; called by muse, mutect2, varscan2
- KCNG3 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1449349202, COSV60150990; called by muse, mutect2, varscan2
- KRT19 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 137/256 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as rs541372182, COSV54181733; called by muse, mutect2, varscan2
- KRT6A | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs749357737, COSV58108441; called by muse, mutect2, varscan2
- MYOM2 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs139030625, COSV50738614; called by muse, mutect2
- PCDH19 | c.2652T>G p.N884K (on ENST00000373034 / NM_001184880.2; = p.N837K on NM_020766.3) | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as rs1213668441; called by muse, mutect2, varscan2
- PCDHA5 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs1554129313, COSV65349263; called by muse, mutect2
- PRMT2 | c.-168G>A | Splice Region (SNP) | VAF 38/68 reads (56%) | catalogued as rs982534360; called by muse, mutect2, varscan2
- RGS7 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV58534807; called by muse, mutect2
- SAP130 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs763552794, COSV52097946; called by muse, mutect2, varscan2
- SLC4A1AP | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1196624165; called by muse, mutect2
- SLC4A4 | c.625C>T p.L209F (on ENST00000264485 / NM_001098484.3; = p.L165F on NM_003759.4) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52615872; called by muse, mutect2, varscan2
- TP63 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.353); catalogued as COSV53202068; called by muse, mutect2, varscan2
- TRPA1 | c.2981T>G p.F994C | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51556492; called by muse, mutect2, varscan2
- VN1R1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as rs768419392; called by muse, mutect2
- XIRP1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs141394135; called by muse, mutect2
- ADGRF5 | c.3377C>G p.T1126S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADGRV1 | c.3266A>G p.Y1089C | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGXT2 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA5 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- APOLD1 | c.282C>G p.S94R (on ENST00000326765 / NM_001130415.2; = p.S63R on NM_030817.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- ASB17 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- BNIPL | c.993_1016del p.Q331_V338del | In Frame Del (DEL) | VAF 9/103 reads (9%) | called by mutect2, pindel
- C4orf17 | c.780T>A p.N260K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.219); called by muse, mutect2
- CATSPERB | c.554C>A p.T185K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CDKN2B | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 100/197 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CTCFL | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- CYP4F11 | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DDB1 | c.2873A>C p.E958A | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); called by muse, mutect2
- DDX60 | c.2312T>G p.L771R | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ERBB3 | c.2786G>T p.R929L | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FABP2 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FER | c.1659C>A p.D553E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- FGF13 | c.154T>G p.F52V | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FUT4 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GTF2H4 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- HERC1 | c.9098A>G p.Y3033C | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IKBKG | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL25 | c.406A>G p.N136D | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KCNH5 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KRT76 | c.1406A>G p.Q469R | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED13L | c.2934T>G p.I978M | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2
- MMP12 | c.1166T>A p.F389Y | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTTP | c.1972G>T p.G658C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2
- OR51A4 | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- OR5L1 | c.909A>C p.K303N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PASD1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.156); called by muse, varscan2
- PRLR | c.469A>T p.I157F | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PSMD7 | c.482A>T p.E161V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.041); called by muse, mutect2
- PSMD7 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2
- RRBP1 | c.3729del p.A1244Pfs*15 (on ENST00000377813 / NM_001365613.2; = p.A811Pfs*15 on NM_004587.3) | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- RYR3 | c.11717A>G p.E3906G (on ENST00000389232; = p.E3907G on NM_001036.6) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- SCOC | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); called by mutect2, varscan2
- SLC22A3 | c.1544T>A p.M515K | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SLCO4C1 | c.1187T>G p.L396* | Nonsense Mutation (SNP) | VAF 26/39 reads (67%) | called by muse, mutect2, varscan2
- STRA8 | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- TMEM229A | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TNK1 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF3 | c.154_178del p.K52Cfs*22 | Frame Shift Del (DEL) | VAF 32/40 reads (80%) | called by mutect2, pindel, varscan2
- TTN | c.52682A>G p.K17561R (on ENST00000591111; = p.K10137R on NM_003319.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | PolyPhen benign (0.274); called by muse, mutect2
- XKR4 | c.443del p.T148Sfs*129 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | called by mutect2, pindel, varscan2
- ZNF43 | c.1555T>A p.F519I | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF541 | c.2776C>T p.H926Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF626 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ABI1 | c.1461C>A p.V487= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV61015632; called by muse, mutect2, varscan2
- DHX35 | c.399C>T p.G133= | Silent (SNP) | VAF 135/263 reads (51%) | catalogued as rs774441384; called by muse, mutect2, varscan2
- DNAH9 | c.6465C>T p.T2155= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs753646311; called by muse, mutect2, varscan2
- EPHB1 | c.1509G>A p.V503= | Silent (SNP) | VAF 104/214 reads (49%) | catalogued as COSV67667044, COSV67672857; called by muse, mutect2, varscan2
- GTF2H4 | c.858G>C p.L286= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- KLHL10 | c.1023G>A p.V341= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs782674695; called by muse, mutect2
- OR2M5 | c.576A>T p.T192= | Silent (SNP) | VAF 24/524 reads (5%) | called by muse, mutect2
- SCEL | c.912C>A p.G304= (on ENST00000349847 / NM_144777.3; = p.G284= on NM_003843.4) | Silent (SNP) | VAF 27/27 reads (100%) | catalogued as rs756164498; called by muse, mutect2, varscan2
- TREM1 | c.549C>T p.V183= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs1315879045; called by muse, mutect2, varscan2
- UNC80 | c.2019T>C p.C673= | Silent (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- ZDHHC15 | c.1005G>A p.T335= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs763194511; called by muse, mutect2, varscan2
- ZNF462 | c.7215G>C p.G2405= | Silent (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- AATK | c.*299C>T | 3'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- ACAP2 | c.*2595T>C | 3'UTR (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- ADGRA1 | c.*493G>C | 3'UTR (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.*958T>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- CD93 | c.-81G>T | 5'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CEP112 | c.2394+25474G>T | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CXCR2 | c.-53T>C | 5'UTR (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- DPT | c.*634G>C | 3'UTR (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- DPY19L2 | c.*1505T>A | 3'UTR (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- DYRK1A | chr21:37514781 T>A | 3'Flank (SNP) | VAF 23/118 reads (19%) | catalogued as rs1338067342; called by muse, mutect2, varscan2
- EFEMP1 | c.*275T>A | 3'UTR (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- FKBP1A | c.*2854C>A | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- FUT3 | c.*134C>T | 3'UTR (SNP) | VAF 70/157 reads (45%) | catalogued as COSV99745103; called by mutect2, varscan2
- GABRB2 | c.*2065G>A | 3'UTR (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- GLRB | c.*724T>G | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- GRB2 | c.*2191A>G | 3'UTR (SNP) | VAF 44/82 reads (54%) | catalogued as rs1400878248; called by muse, mutect2, varscan2
- GUCA1C | c.*205G>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- IVNS1ABP | c.*350G>C | 3'UTR (SNP) | VAF 39/143 reads (27%) | called by muse, mutect2, varscan2
- JCAD | c.*852G>A | 3'UTR (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- KLHL14 | c.*1187G>C | 3'UTR (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- KNCN | c.*154dup | 3'UTR (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- LRRC32 | c.*944A>G | 3'UTR (SNP) | VAF 28/39 reads (72%) | catalogued as rs1565402359; called by muse, mutect2
- MARCHF1 | c.*1293T>C | 3'UTR (SNP) | VAF 5/47 reads (11%) | catalogued as rs866177096; called by muse, mutect2, varscan2
- MIOX | c.*9C>A | 3'UTR (SNP) | VAF 98/182 reads (54%) | called by muse, mutect2, varscan2
- MLX | c.*200T>A | 3'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- MUC21 | c.-127C>T | 5'UTR (SNP) | VAF 27/141 reads (19%) | called by muse, mutect2, varscan2
- NRP2 | c.*2724G>A | 3'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- PCYOX1L | c.*115G>T | 3'UTR (SNP) | VAF 3/40 reads (8%) | catalogued as rs945900633; called by muse, mutect2
- PCYT1B | c.*1179C>A | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PDCD6IP | c.717+60dup | Intron (INS) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.*2136A>G | 3'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as rs957154764; called by muse, mutect2, varscan2
- RABL2A | c.-57G>T | 5'UTR (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- RNF170 | chr8:42896630 G>C | 5'Flank (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- RRAGD | c.*3238T>A | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- SAMD5 | c.*404T>G | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- SENP6 | c.-105G>T | 5'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- SLC2A13 | c.*3018A>G | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- SLC36A1 | c.-164C>T | 5'UTR (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- SNRPE | c.*731A>G | 3'UTR (SNP) | VAF 87/115 reads (76%) | called by muse, mutect2, varscan2
- SP8 | chr7:20783675 C>T | 3'Flank (SNP) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- TCOF1 | c.2860-3969A>C | Intron (SNP) | VAF 89/179 reads (50%) | called by muse, mutect2, varscan2
- TRIM33 | c.*2813C>G | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- TSGA10 | chr2:98997860 A>G | 3'Flank (SNP) | VAF 56/132 reads (42%) | called by muse, mutect2, varscan2
- UGGT1 | c.*5568C>G | 3'UTR (SNP) | VAF 58/138 reads (42%) | called by muse, mutect2, varscan2
- VAV3 | c.*1634G>A | 3'UTR (SNP) | VAF 33/47 reads (70%) | called by muse, mutect2, varscan2
- YAF2 | c.*3135T>G | 3'UTR (SNP) | VAF 46/94 reads (49%) | called by muse, varscan2
- ZFAT | c.*584C>T | 3'UTR (SNP) | VAF 67/168 reads (40%) | catalogued as rs1408553249; called by muse, mutect2, varscan2
